CCDI case PBCTHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0876a109-36bb-4dd2-a1d8-3c626927a5fc

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.8 years (1,382 days).

Biospecimens (3 samples)
- Sample 0DYUZ7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYUZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DYV1L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
